Somatic mutation profile of tumor specimen TARGET-40-PARJXU-01A (aliquot TARGET-40-PARJXU-01A-01D) from TARGET case TARGET-40-PARJXU, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 12.7 years (4,624 days).
Specimen TARGET-40-PARJXU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b8d2e0bf-e63a-47ca-b830-0259ede1e075.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PARJXU-10A (Blood Derived Normal), aliquot TARGET-40-PARJXU-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a2e2f07b-1da1-459c-8702-84a031c646d6

The open-access MAF lists 63 somatic variants for this specimen: 43 protein-altering or splice-affecting, 7 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 7, Intron 6, Nonsense Mutation 4, RNA 4, 3'UTR 2, Splice Region 2, 5'Flank 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCOR | c.4072T>C p.S1358P (on ENST00000378444 / NM_001123385.2; = p.S1324P on NM_017745.6) | Missense Mutation (SNP) | VAF 118/738 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as rs758919208, COSV60703799; called by muse, mutect2, varscan2
- CDH1 | c.2081T>A p.V694D | Missense Mutation (SNP) | VAF 164/691 reads (24%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV55730162; called by muse, mutect2, varscan2
- CYLC2 | c.146C>T p.S49L | Missense Mutation (SNP) | VAF 47/386 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV66337604; called by muse, mutect2, varscan2
- DGKK | c.1934C>G p.A645G | Missense Mutation (SNP) | VAF 125/296 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.366); catalogued as COSV101053025; called by muse, mutect2, varscan2
- DIPK1B | c.147C>G p.H49Q | Missense Mutation (SNP) | VAF 86/461 reads (19%) | SIFT tolerated (0.74); PolyPhen benign (0.009); catalogued as COSV100865019; called by muse, mutect2, varscan2
- DNAJC6 | c.349C>T p.R117* | Nonsense Mutation (SNP) | VAF 440/835 reads (53%) | catalogued as rs1385103341; called by muse, mutect2, varscan2
- FAM47A | c.1519G>C p.E507Q | Missense Mutation (SNP) | VAF 120/962 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs5973088, COSV60494128, COSV60495398; called by muse, varscan2
- ITGB4 | c.13C>T p.R5C | Missense Mutation (SNP) | VAF 33/594 reads (6%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs141077392; called by muse, mutect2
- PCSK1 | c.1312C>T p.R438* | Nonsense Mutation (SNP) | VAF 34/336 reads (10%) | catalogued as rs974974563; called by muse, mutect2, varscan2
- PDE4B | c.1660C>G p.Q554E | Missense Mutation (SNP) | VAF 20/334 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1428691676; called by muse, mutect2
- PLS1 | c.158G>A p.R53H | Missense Mutation (SNP) | VAF 53/722 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs757919995, COSV61835305; called by muse, mutect2
- SERPINB12 | c.1043C>A p.T348N | Missense Mutation (SNP) | VAF 135/964 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV54035013; called by muse, mutect2, varscan2
- SYTL5 | c.1210G>T p.V404L | Missense Mutation (SNP) | VAF 775/1295 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0.395); catalogued as COSV99936992; called by muse, mutect2, varscan2
- TSHZ3 | c.2794C>T p.R932W | Missense Mutation (SNP) | VAF 24/440 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1270874522, COSV53663245, COSV53670748; called by muse, mutect2
- ZIM2 | c.190+7C>A | Splice Region (SNP) | VAF 48/278 reads (17%) | catalogued as COSV55630732; called by muse, varscan2
- AGT | c.1079C>A p.T360N | Missense Mutation (SNP) | VAF 79/810 reads (10%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.698); called by muse, mutect2
- BCHE | c.890C>A p.P297H | Missense Mutation (SNP) | VAF 194/362 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- BRINP3 | c.1883A>T p.Y628F | Missense Mutation (SNP) | VAF 160/1867 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2
- CACNA1G | c.5896G>T p.A1966S | Missense Mutation (SNP) | VAF 106/393 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- CFAP54 | c.4947A>C p.E1649D | Missense Mutation (SNP) | VAF 112/378 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- CYTH4 | c.119T>C p.I40T | Missense Mutation (SNP) | VAF 18/586 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.241); called by muse, mutect2
- FAM200A | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 75/340 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GBA2 | c.1805C>A p.P602Q | Missense Mutation (SNP) | VAF 44/578 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- GOLGA8S | c.1492G>A p.D498N | Missense Mutation (SNP) | VAF 55/1092 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.224); called by muse, mutect2
- KLK6 | c.556G>C p.E186Q | Missense Mutation (SNP) | VAF 56/872 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.026); called by muse, mutect2
- MAPK9 | c.378A>T p.E126D | Missense Mutation (SNP) | VAF 18/268 reads (7%) | SIFT tolerated (0.62); PolyPhen benign (0.007); called by muse, mutect2
- MTF1 | c.1576A>C p.T526P | Missense Mutation (SNP) | VAF 139/494 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- MVB12A | c.709T>C p.S237P | Missense Mutation (SNP) | VAF 10/212 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); called by muse, mutect2
- MYH15 | c.4840G>T p.D1614Y | Missense Mutation (SNP) | VAF 22/394 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); called by muse, mutect2
- OR1M1 | c.106C>A p.L36M | Missense Mutation (SNP) | VAF 281/689 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PSD3 | c.2176-2A>G p.X726_splice (on ENST00000440756; = p.X725_splice on NM_015310.4) | Splice Site (SNP) | VAF 75/208 reads (36%) | called by muse, mutect2, varscan2
- SAMD15 | c.1100C>T p.S367L | Missense Mutation (SNP) | VAF 146/658 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.021); called by muse, mutect2
- SLC9A2 | c.1688A>G p.H563R | Missense Mutation (SNP) | VAF 42/216 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.605); called by muse, mutect2, varscan2
- STAP1 | c.420A>T p.E140D | Missense Mutation (SNP) | VAF 30/878 reads (3%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.944); called by muse, mutect2
- TDRD15 | c.2060_2096del p.K687Ifs*26 | Frame Shift Del (DEL) | VAF 46/264 reads (17%) | called by mutect2, pindel
- TPST1 | c.1102C>T p.Q368* | Nonsense Mutation (SNP) | VAF 122/237 reads (51%) | called by muse, mutect2, varscan2
- TRIM46 | c.1293G>T p.E431D | Missense Mutation (SNP) | VAF 33/1044 reads (3%) | SIFT tolerated (0.62); PolyPhen benign (0.003); called by muse, mutect2
- TRIM51GP | c.1130T>G p.L377R | Missense Mutation (SNP) | VAF 46/701 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2
- USP13 | c.2461A>T p.S821C | Missense Mutation (SNP) | VAF 165/310 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- WASH6P | c.721-7C>G | Splice Region (SNP) | VAF 270/970 reads (28%) | called by muse, mutect2, varscan2
- WASH6P | c.1308C>G p.I436M | Missense Mutation (SNP) | VAF 116/356 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, varscan2
- ZFHX3 | c.5880T>A p.Y1960* | Nonsense Mutation (SNP) | VAF 33/934 reads (4%) | called by muse, mutect2
- ZMAT1 | c.1026G>C p.M342I | Missense Mutation (SNP) | VAF 475/595 reads (80%) | SIFT tolerated (0.38); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- APOA4 | c.316C>T p.L106= | Silent (SNP) | VAF 100/343 reads (29%) | catalogued as COSV63360955; called by muse, mutect2, varscan2
- BYSL | c.102G>A p.R34= | Silent (SNP) | VAF 51/252 reads (20%) | called by muse, mutect2, varscan2
- BYSL | c.453C>A p.I151= | Silent (SNP) | VAF 163/785 reads (21%) | called by muse, mutect2, varscan2
- EEF2 | c.1635C>A p.I545= | Silent (SNP) | VAF 409/495 reads (83%) | called by muse, mutect2, varscan2
- ILVBL | c.1045C>T p.L349= | Silent (SNP) | VAF 136/755 reads (18%) | called by muse, varscan2
- NR1H4 | c.906G>A p.T302= (on ENST00000551379 / NM_001206993.2; = p.T288= on NM_005123.4) | Silent (SNP) | VAF 86/287 reads (30%) | catalogued as rs1193074710; called by muse, mutect2, varscan2
- STAG3 | c.1884A>G p.Q628= | Silent (SNP) | VAF 261/471 reads (55%) | catalogued as rs1435582421; called by muse, mutect2, varscan2
- AC027369.3 | n.433G>A | RNA (SNP) | VAF 77/277 reads (28%) | called by muse, mutect2, varscan2
- BMS1P16 | n.635G>A | RNA (SNP) | VAF 113/311 reads (36%) | called by muse, mutect2, varscan2
- GFAP | c.1291+25G>A | Intron (SNP) | VAF 468/899 reads (52%) | catalogued as rs369986771; called by muse, mutect2, varscan2
- HTR3B | c.*81G>C | 3'UTR (SNP) | VAF 82/158 reads (52%) | catalogued as rs1245103886; called by muse, mutect2, varscan2
- KLRC2 | c.*21C>T | 3'UTR (SNP) | VAF 75/275 reads (27%) | catalogued as rs1296303505; called by muse, mutect2, varscan2
- MED20 | c.14+165C>T | Intron (SNP) | VAF 50/196 reads (26%) | catalogued as rs1337254792; called by muse, mutect2, varscan2
- MTHFR | c.476-18C>T | Intron (SNP) | VAF 131/782 reads (17%) | catalogued as COSV64701735; called by muse, mutect2, varscan2
- OR10D1P | n.645C>A | RNA (SNP) | VAF 157/492 reads (32%) | called by muse, mutect2, varscan2
- OR6Y1 | chr1:158548127 A>G | 5'Flank (SNP) | VAF 54/958 reads (6%) | called by muse, mutect2
- OR7E55P | n.273C>A | RNA (SNP) | VAF 191/501 reads (38%) | called by muse, mutect2, varscan2
- RHOT2 | c.277-119T>G | Intron (SNP) | VAF 61/106 reads (58%) | called by muse, mutect2, varscan2
- TYROBP | c.229+89G>A | Intron (SNP) | VAF 172/378 reads (46%) | called by muse, mutect2, varscan2
- WASH6P | c.301-39C>T | Intron (SNP) | VAF 93/416 reads (22%) | catalogued as rs1316774912; called by muse, mutect2, varscan2
